Somatic mutation profile of tumor specimen C3L-05261-03 (aliquot CPT0340990007) from CPTAC case C3L-05261, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 40.5 years (14,788 days).
Specimen C3L-05261-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51e2966a-410b-4efe-aad4-6009a0e8bca8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05261-31 (Blood Derived Normal), aliquot CPT0341070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c30eb9e-eb24-4c52-b15d-a151b8e36b81

The open-access MAF lists 421 somatic variants for this specimen: 253 protein-altering or splice-affecting, 150 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 150, Nonsense Mutation 23, Intron 8, Splice Region 6, 5'Flank 4, 3'UTR 3, RNA 2, Splice Site 2, Frame Shift Del 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.3577-1G>T p.X1193_splice (on ENST00000404938 / NM_001163941.2; = p.X748_splice on NM_178559.6) | Splice Site (SNP) | VAF 30/337 reads (9%) | catalogued as COSV99329522; called by muse, mutect2
- ABCD1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 145/296 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960035, COSV99497570; called by muse, mutect2, varscan2
- ABCF2 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.833); catalogued as rs1175580450, COSV55184928; called by muse, mutect2, varscan2
- ADAM18 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1280515690; called by muse, mutect2, varscan2
- ANO3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs868398613, COSV56789977; called by muse, mutect2, varscan2
- ASNSD1 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs755759127, COSV99641280; called by muse, mutect2, varscan2
- BTBD10 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs767267622; called by muse, mutect2, varscan2
- BUB1B | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 42/437 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs77520855; ClinVar: uncertain significance; called by muse, mutect2
- CABP2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs779624248; called by muse, mutect2, varscan2
- CARD14 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 159/466 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.22); catalogued as rs1273763320; called by muse, mutect2, varscan2
- CBY2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779360170; called by muse, mutect2, varscan2
- CCDC88C | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs1439884822; called by muse, mutect2, varscan2
- CD163 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV63131983; called by muse, mutect2, varscan2
- CDH9 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50257951; called by muse, mutect2, varscan2
- CFTR | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1417904716, CD941634, COSV50040996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHIT1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs772910185, COSV55148726; called by muse, mutect2, varscan2
- COL4A6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142121908; called by muse, mutect2, varscan2
- CREB3L2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 47/506 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57798501; called by muse, mutect2
- CSMD1 | c.9320G>A p.G3107E (on ENST00000520002; = p.G3106E on NM_033225.6) | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100155255; called by muse, mutect2, varscan2
- CYP2B6 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1568561013, COSV57842974; called by muse, mutect2, varscan2
- CYP2W1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 148/386 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.309); catalogued as rs769076234; called by muse, mutect2, varscan2
- DDX10 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758002404; called by muse, mutect2, varscan2
- DISP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53822416; called by muse, mutect2, varscan2
- DMGDH | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs778901952; called by muse, mutect2
- DNAH3 | c.10429C>T p.R3477* | Nonsense Mutation (SNP) | VAF 58/386 reads (15%) | catalogued as rs750184108; called by muse, mutect2, varscan2
- DNAH5 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs200314274, COSV54230788; called by muse, mutect2, varscan2
- DNAH8 | c.9364G>A p.E3122K | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.792); catalogued as COSV59487031; called by muse, mutect2, varscan2
- DNAH9 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV52340315; called by muse, mutect2, varscan2
- DOCK2 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV56981234; called by muse, mutect2, varscan2
- DPPA2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs922189877, COSV72118023; called by muse, mutect2, varscan2
- DRD3 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs144644130; called by muse, mutect2, varscan2
- DSCAM | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs372711039; called by muse, mutect2, varscan2
- EPPIN | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs915255610, COSV60549148; called by muse, mutect2, varscan2
- FAM135B | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 152/422 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99420005; called by muse, mutect2, varscan2
- FAM13C | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs781708491, COSV53243827; called by muse, mutect2
- FAM90A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562876348, COSV56710170; called by muse, mutect2, varscan2
- FBXW7 | c.1673C>T p.S558F (on ENST00000281708 / NM_001349798.2; = p.S478F on NM_018315.5) | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55929615; called by muse, mutect2, varscan2
- FLACC1 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 45/336 reads (13%) | catalogued as rs146041521; called by muse, mutect2, varscan2
- FLRT2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 56/447 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV100421198, COSV58138830; called by muse, mutect2, varscan2
- FRMPD2 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 29/151 reads (19%) | catalogued as rs375582024, COSV100563584; called by muse, mutect2, varscan2
- FUS | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1165095258, CM091088; called by muse, mutect2, varscan2
- G6PC2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs574976550, COSV56371930; called by muse, mutect2, varscan2
- GAL3ST3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 51/460 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as rs762977263, COSV61748818; called by muse, mutect2, varscan2
- GAS7 | c.1165C>T p.L389F (on ENST00000432992 / NM_201433.2; = p.L249F on NM_003644.3) | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100096700; called by muse, mutect2, varscan2
- GJA10 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV65354940; called by muse, mutect2, varscan2
- GLDN | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 113/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59088823; called by muse, mutect2, varscan2
- HEG1 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs904082752; called by muse, mutect2, varscan2
- HRH1 | c.1364G>T p.W455L | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67955498; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- KCNA10 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774267324; called by muse, mutect2, varscan2
- KCND2 | c.1278G>A p.K426= | Splice Region (SNP) | VAF 34/242 reads (14%) | catalogued as rs1350140770, COSV58577369; called by muse, mutect2, varscan2
- KIAA1109 | c.14242C>T p.P4748S | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs141798602, COSV52697577; called by muse, mutect2, varscan2
- KIF5C | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV68480286; called by muse, mutect2, varscan2
- KLK15 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334556379, COSV56826981; called by muse, mutect2, varscan2
- LANCL2 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 47/419 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs143775487, COSV54653452; called by muse, mutect2, varscan2
- MACF1 | c.9821C>T p.S3274F | Missense Mutation (SNP) | VAF 90/186 reads (48%) | catalogued as rs1473656942; called by muse, mutect2, varscan2
- MAN2A1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867969853; called by muse, mutect2, varscan2
- MAP3K4 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs756547877, COSV100815789; called by muse, mutect2, varscan2
- MAPK13 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs765793199, COSV52984865; called by muse, mutect2
- MTUS2 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101462165; called by muse, mutect2, varscan2
- MTUS2 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs776054880, COSV70917779; called by muse, mutect2, varscan2
- MUC16 | c.9098G>A p.S3033N | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as rs1568904813; called by muse, mutect2, varscan2
- MUC16 | c.5152G>A p.G1718R | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as rs1373061314; called by muse, mutect2, varscan2
- MYH11 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 144/397 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100257873; called by muse, mutect2, varscan2
- MYH4 | c.5786G>T p.R1929L | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV55117232; called by muse, mutect2, varscan2
- NAA11 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs868363838, COSV54514672; called by muse, mutect2, varscan2
- NLRP2 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 71/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755680979, COSV54760442; called by muse, mutect2, varscan2
- NME8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1044473414, COSV52253335; called by muse, mutect2, varscan2
- NOMO1 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV99814649; called by muse, mutect2, varscan2
- NT5C1B | c.823G>A p.E275K (on ENST00000359846 / NM_001199086.2; = p.E215K on NM_033253.4) | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.36); catalogued as rs761163465; called by muse, varscan2
- ODF4 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 63/453 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1308064335, COSV60271709; called by muse, mutect2
- OPRD1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as rs1177963730; called by muse, mutect2, varscan2
- OR10H2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as COSV100008883; called by muse, mutect2, varscan2
- OR4A15 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as rs753415282, COSV100124011, COSV59033532; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 13/241 reads (5%) | catalogued as COSV53458913, COSV53460428; called by muse, mutect2
- OR52E8 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs551544283, COSV66205646; called by muse, mutect2, varscan2
- OR9Q2 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV61112508; called by muse, mutect2, varscan2
- PAPPA2 | c.3935-1G>A p.X1312_splice | Splice Site (SNP) | VAF 43/226 reads (19%) | catalogued as COSV62802101; called by muse, mutect2, varscan2
- PCDHA4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs782375351; called by muse, mutect2, varscan2
- PCDHA7 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1554134227; called by muse, mutect2, varscan2
- PCNX2 | c.3118C>T p.L1040F | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs1355719976, COSV50838122; called by muse, mutect2
- PHF19 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1352804030; called by muse, mutect2, varscan2
- PIGQ | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs368598376; called by muse, mutect2, varscan2
- PIK3CG | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 52/474 reads (11%) | catalogued as COSV63246685; called by muse, mutect2, varscan2
- PRUNE2 | c.7772T>C p.L2591S | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs771938925; called by muse, mutect2, varscan2
- PSME4 | c.3601C>T p.R1201* | Nonsense Mutation (SNP) | VAF 32/192 reads (17%) | catalogued as COSV101122300, COSV66367257; called by muse, mutect2, varscan2
- PTK7 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 54/499 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs769623531, COSV57849192; called by muse, mutect2, varscan2
- RAG2 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV57557346, COSV57557689; called by muse, mutect2, varscan2
- REPIN1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 212/582 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1411912223; called by muse, mutect2, varscan2
- ROR2 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs757252249, COSV65216326; called by muse, mutect2, varscan2
- RTN4IP1 | c.498C>T p.V166= | Splice Region (SNP) | VAF 24/252 reads (10%) | catalogued as rs762291141; called by muse, mutect2
- RYR3 | c.13069G>A p.E4357K (on ENST00000389232; = p.E4358K on NM_001036.6) | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV66811271; called by muse, mutect2, varscan2
- SALL1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51755307; called by muse, mutect2, varscan2
- SH2D2A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1237620580; called by muse, mutect2
- SHISA9 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1321323622; called by muse, mutect2, varscan2
- SMCHD1 | c.5930T>C p.V1977A | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1430043041; called by muse, mutect2, varscan2
- SPTA1 | c.5190G>A p.E1730= | Splice Region (SNP) | VAF 29/305 reads (10%) | catalogued as rs867887614, COSV100935761, COSV63748741; called by muse, mutect2, varscan2
- SPTBN1 | c.4463A>G p.H1488R | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.445); catalogued as rs1452833528; called by muse, mutect2, varscan2
- SRGN | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424053609, COSV54344881; called by muse, mutect2, varscan2
- SRPX2 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 114/211 reads (54%) | catalogued as rs970325054; called by muse, varscan2
- STAB1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs1303207985, COSV58735538; called by muse, mutect2, varscan2
- STARD9 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs752656492, COSV51901795; called by muse, mutect2, varscan2
- STOX2 | c.1365T>A p.F455L | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1255840608; called by muse, mutect2, varscan2
- TBC1D10C | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as rs376310444; called by muse, mutect2, varscan2
- TBX15 | c.1364C>T p.S455L (on ENST00000369429 / NM_001330677.2; = p.S349L on NM_152380.3) | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as rs141953431; called by muse, mutect2, varscan2
- TIGD7 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 47/311 reads (15%) | catalogued as rs767003342, COSV51915849; called by muse, mutect2, varscan2
- TIMM17A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66171388; called by muse, mutect2, varscan2
- TLR5 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMEM231 | c.770C>T p.S257F (on ENST00000258173 / NM_001077418.3; = p.S286F on NM_001077416.2) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.185); catalogued as COSV50737896; called by muse, mutect2, varscan2
- TPO | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV61111086; called by muse, mutect2
- TRIM58 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 65/422 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs143805378, COSV63569329; called by muse, mutect2
- TRPA1 | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 36/303 reads (12%) | catalogued as COSV100083955; called by muse, mutect2, varscan2
- TTN | c.92477G>A p.G30826E (on ENST00000591111; = p.G23402E on NM_003319.4) | Missense Mutation (SNP) | VAF 46/483 reads (10%) | PolyPhen probably damaging (1); catalogued as COSV59978906; called by muse, mutect2
- UNC5B | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV58981011; called by muse, mutect2, varscan2
- UTP20 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99880547; called by muse, mutect2, varscan2
- WDR93 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99175631; called by muse, mutect2, varscan2
- YIPF7 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV60656095; called by muse, mutect2, varscan2
- ZNF560 | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs538535192; called by muse, mutect2, varscan2
- ZNF582 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV56734100; called by muse, mutect2, varscan2
- ZNF585A | c.1226C>T p.S409L (on ENST00000292841 / NM_001288800.2; = p.S354L on NM_152655.3) | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs146470162; called by muse, mutect2
- ZNF700 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1212766672, COSV54315279; called by muse, mutect2, varscan2
- ZSCAN18 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs773660625; called by muse, mutect2, varscan2
- ADAMTS9 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- ADGRF1 | c.1984T>C p.F662L | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.9238A>T p.K3080* | Nonsense Mutation (SNP) | VAF 121/379 reads (32%) | called by muse, mutect2, varscan2
- ALDOA | c.439C>T p.P147S (on ENST00000642816 / NM_001243177.4; = p.P93S on NM_184041.5) | Missense Mutation (SNP) | VAF 121/362 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKFN1 | c.3844G>A p.G1282S (on ENST00000653862; = p.G1135S on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ANKK1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 66/396 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANKRD45 | c.676A>T p.R226* | Nonsense Mutation (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
- ANO6 | c.1453T>C p.S485P | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ASXL3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ATAD2B | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GALT1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BEST3 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRAF | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CACNA2D1 | c.3214G>T p.G1072C (on ENST00000356253 / NM_001366867.1; = p.G1060C on NM_000722.4) | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD300LD | c.403T>G p.W135G | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CKAP2L | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CMPK2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COL5A1 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD1 | c.5432G>A p.R1811K (on ENST00000520002; = p.R1810K on NM_033225.6) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DAB1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DNAH12 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2AK1 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ELMO1 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FAM47C | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 145/279 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FANCE | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW9 | c.1100C>T p.S367F (on ENST00000587955; = p.S347F on NM_032301.3) | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FYB2 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GABRE | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GABRP | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPIHBP1 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GREB1 | c.4992G>A p.R1664= | Splice Region (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- HBD | c.165del p.M56Wfs*6 | Frame Shift Del (DEL) | VAF 46/331 reads (14%) | called by mutect2, pindel, varscan2
- HCFC1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HERC2 | c.6073T>G p.C2025G | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- HTR3B | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- IGLV7-46 | c.204_209del p.I69_Y70del | In Frame Del (DEL) | VAF 36/255 reads (14%) | called by mutect2, pindel, varscan2
- IGSF1 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- IRAG2 | c.3947C>T p.P1316L (on ENST00000636465; = p.P361L on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRS2 | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 161/506 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ITGA10 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 167/354 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, varscan2
- JAKMIP3 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- KATNBL1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- KDM6B | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF26B | c.4732G>A p.E1578K | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LRIG3 | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- LRP1B | c.11601T>A p.C3867* | Nonsense Mutation (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- MAFA | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MAGI1 | c.2902C>T p.P968S (on ENST00000402939 / NM_001033057.2; = p.P996S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/417 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MCTP2 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEI1 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MFSD6L | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MINDY4B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MLIP | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MMP19 | c.306C>T p.G102= | Splice Region (SNP) | VAF 53/191 reads (28%) | called by muse, mutect2, varscan2
- MPEG1 | c.338del p.Y113Sfs*24 | Frame Shift Del (DEL) | VAF 46/302 reads (15%) | called by mutect2, pindel, varscan2
- MRM3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTMR12 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 189/436 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.32234G>A p.G10745E | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MYO15B | c.8415G>A p.L2805= | Splice Region (SNP) | VAF 54/208 reads (26%) | called by muse, mutect2, varscan2
- MYO9A | c.4417C>T p.Q1473* | Nonsense Mutation (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- NBAS | c.6352C>T p.H2118Y | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NCKAP5L | c.3928C>T p.P1310S | Missense Mutation (SNP) | VAF 124/523 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NIM1K | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.4700G>A p.W1567* | Nonsense Mutation (SNP) | VAF 64/411 reads (16%) | called by muse, mutect2, varscan2
- OR1D5 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7C1 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- P2RY6 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAFAH1B1 | c.841T>G p.C281G | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PAGE2B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PCDHA3 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PCDHB4 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PDZD7 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PER2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 59/361 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PHGR1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 56/506 reads (11%) | PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PIGR | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R5 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PKHD1L1 | c.6769C>T p.Q2257* | Nonsense Mutation (SNP) | VAF 31/316 reads (10%) | called by muse, mutect2
- POLI | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- POLQ | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEE | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 66/524 reads (13%) | called by muse, mutect2, varscan2
- PRRC2B | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- PSG5 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PTGIR | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 70/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRF | c.3646C>T p.P1216S | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- RFPL3 | c.370C>T p.Q124* (on ENST00000249007 / NM_001098535.1; = p.Q95* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 37/209 reads (18%) | called by muse, mutect2, varscan2
- RIMBP3B | c.4667C>A p.S1556Y | Missense Mutation (SNP) | VAF 71/948 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2
- RP1 | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RTL1 | c.2838G>A p.M946I | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SCN10A | c.2969A>G p.N990S | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SERPINE1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A3 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC52A3 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, varscan2
- SLC9C1 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2
- SNRK | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.271); called by muse, varscan2
- SNRNP70 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 40/356 reads (11%) | called by muse, mutect2, varscan2
- SPO11 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ST8SIA2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 84/361 reads (23%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF11L13 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 97/366 reads (27%) | called by muse, mutect2, varscan2
- TAMALIN | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TDRD5 | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TIMM10B | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMM10B | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMM17A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TLCD3B | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLN2 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- TNXB | c.11469G>A p.W3823* (on ENST00000647633; = p.W3576* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 75/1618 reads (5%) | called by muse, mutect2
- TPH1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TRAV22 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TRIM69 | c.1352G>A p.G451E (on ENST00000329464 / NM_182985.5; = p.G292E on NM_080745.5) | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC5 | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRPM6 | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRPV6 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 46/544 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.16); called by muse, mutect2
- TSSK1B | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TXNRD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC79 | c.5654C>T p.S1885F (on ENST00000393151 / NM_001346218.2; = p.S1708F on NM_020818.5) | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UTRN | c.7948C>T p.P2650S | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- VRK3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- WDR93 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 71/288 reads (25%) | called by muse, mutect2, varscan2
- WFDC13 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 47/361 reads (13%) | called by muse, mutect2, varscan2
- ZDHHC15 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ZNF10 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ZNF148 | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF222 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZNF317 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF444 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF483 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF546 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF875 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCD1 | c.789C>T p.P263= | Silent (SNP) | VAF 141/293 reads (48%) | called by muse, mutect2, varscan2
- ACR | c.864G>A p.K288= | Silent (SNP) | VAF 48/379 reads (13%) | catalogued as COSV53360380; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1143G>A p.L381= | Silent (SNP) | VAF 79/490 reads (16%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2226C>T p.F742= | Silent (SNP) | VAF 42/359 reads (12%) | called by muse, mutect2, varscan2
- AK7 | c.147T>C p.I49= | Silent (SNP) | VAF 36/349 reads (10%) | called by muse, mutect2
- ALPK3 | c.4974G>A p.K1658= | Silent (SNP) | VAF 54/376 reads (14%) | catalogued as rs1441226520; called by muse, mutect2, varscan2
- ANKK1 | c.2034C>T p.L678= | Silent (SNP) | VAF 49/340 reads (14%) | called by muse, mutect2, varscan2
- ASAP1 | c.639C>T p.L213= | Silent (SNP) | VAF 94/340 reads (28%) | called by muse, mutect2, varscan2
- ASTN2 | c.1185G>A p.G395= (on ENST00000313400 / NM_001365069.1; = p.G344= on NM_014010.5) | Silent (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
- ATP12A | c.2868G>A p.R956= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as COSV54517980; called by muse, mutect2, varscan2
- ATP4A | c.396G>A p.E132= | Silent (SNP) | VAF 88/279 reads (32%) | called by muse, mutect2, varscan2
- AVIL | c.699C>A p.I233= | Silent (SNP) | VAF 45/327 reads (14%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1245G>A p.E415= | Silent (SNP) | VAF 74/298 reads (25%) | called by muse, mutect2, varscan2
- BDKRB2 | c.204C>T p.F68= | Silent (SNP) | VAF 95/369 reads (26%) | catalogued as rs943088316, COSV60014259; called by muse, mutect2, varscan2
- BMT2 | c.330T>G p.G110= | Silent (SNP) | VAF 75/288 reads (26%) | called by muse, mutect2, varscan2
- C1orf94 | c.756G>A p.K252= (on ENST00000488417 / NM_001134734.2; = p.K62= on NM_032884.5) | Silent (SNP) | VAF 141/289 reads (49%) | catalogued as rs1476602930, COSV64914272; called by muse, varscan2
- CACNA1A | c.1389G>A p.L463= | Silent (SNP) | VAF 32/220 reads (15%) | catalogued as COSV64190715; called by muse, mutect2, varscan2
- CACNA1D | c.2547G>A p.S849= (on ENST00000350061 / NM_001128840.3; = p.S869= on NM_000720.4) | Silent (SNP) | VAF 68/353 reads (19%) | catalogued as rs760086264, COSV99857566; called by muse, mutect2, varscan2
- CDK3 | c.246C>T p.F82= | Silent (SNP) | VAF 41/362 reads (11%) | catalogued as COSV100044495; called by muse, mutect2, varscan2
- CELSR3 | c.1917C>T p.I639= | Silent (SNP) | VAF 61/321 reads (19%) | called by muse, mutect2, varscan2
- CFAP54 | c.1236C>T p.V412= | Silent (SNP) | VAF 105/411 reads (26%) | called by muse, mutect2, varscan2
- CLEC18B | c.612T>C p.C204= | Silent (SNP) | VAF 42/474 reads (9%) | catalogued as rs1450099179; called by muse, mutect2
- CLVS1 | c.414G>A p.R138= | Silent (SNP) | VAF 99/388 reads (26%) | catalogued as rs267601963, COSV57971306; called by muse, mutect2, varscan2
- CNTNAP5 | c.2475C>T p.S825= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as rs536683996; called by muse, mutect2, varscan2
- COL28A1 | c.933C>T p.S311= | Silent (SNP) | VAF 96/305 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.2985C>T p.P995= | Silent (SNP) | VAF 50/504 reads (10%) | catalogued as rs768883188; ClinVar: likely benign; called by muse, mutect2
- COL9A3 | c.357C>T p.L119= | Silent (SNP) | VAF 53/343 reads (15%) | catalogued as COSV59654119; called by muse, mutect2, varscan2
- CRNN | c.792G>A p.Q264= | Silent (SNP) | VAF 283/721 reads (39%) | catalogued as rs1283679908; called by muse, mutect2, varscan2
- CYP2F1 | c.1284C>A p.P428= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- CYP7B1 | c.1512G>A p.V504= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- DACT1 | c.1038C>T p.V346= | Silent (SNP) | VAF 49/431 reads (11%) | called by muse, mutect2, varscan2
- DNAH7 | c.6588A>G p.E2196= | Silent (SNP) | VAF 26/216 reads (12%) | called by muse, varscan2
- EFHC2 | c.1368A>C p.S456= | Silent (SNP) | VAF 49/201 reads (24%) | called by muse, mutect2, varscan2
- ELOVL5 | c.423C>T p.V141= | Silent (SNP) | VAF 43/505 reads (9%) | called by muse, mutect2
- EMB | c.228C>T p.I76= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV57480487; called by muse, mutect2, varscan2
- EPHB3 | c.1038G>A p.V346= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- EVPL | c.4305G>A p.V1435= | Silent (SNP) | VAF 61/548 reads (11%) | called by muse, mutect2, varscan2
- FSHR | c.1689C>T p.S563= | Silent (SNP) | VAF 66/406 reads (16%) | called by muse, mutect2, varscan2
- FSIP2 | c.14709C>T p.I4903= | Silent (SNP) | VAF 36/256 reads (14%) | called by muse, mutect2, varscan2
- GHITM | c.75C>T p.S25= | Silent (SNP) | VAF 46/239 reads (19%) | catalogued as rs1399679319; called by muse, mutect2, varscan2
- GPRIN2 | c.39C>T p.P13= | Silent (SNP) | VAF 52/882 reads (6%) | catalogued as rs782407923; called by muse, mutect2
- GRIN2B | c.1980G>A p.V660= | Silent (SNP) | VAF 33/281 reads (12%) | called by muse, mutect2, varscan2
- GSTT2B | c.420C>T p.D140= | Silent (SNP) | VAF 58/575 reads (10%) | called by muse, mutect2, varscan2
- HAO2 | c.21A>C p.T7= | Silent (SNP) | VAF 40/267 reads (15%) | called by muse, mutect2, varscan2
- HMX1 | c.66G>A p.E22= | Silent (SNP) | VAF 56/335 reads (17%) | called by muse, mutect2, varscan2
- HPS1 | c.684C>T p.S228= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as rs1360659738; called by muse, mutect2, varscan2
- HYAL4 | c.945C>T p.F315= | Silent (SNP) | VAF 35/229 reads (15%) | catalogued as COSV56138167; called by muse, mutect2, varscan2
- IGF1R | c.2193C>T p.F731= | Silent (SNP) | VAF 38/207 reads (18%) | catalogued as rs1289742415, COSV51273780; called by muse, mutect2, varscan2
- IQCA1L | c.1719G>A p.K573= | Silent (SNP) | VAF 57/540 reads (11%) | called by muse, mutect2, varscan2
- ISLR | c.1269C>T p.F423= | Silent (SNP) | VAF 105/380 reads (28%) | catalogued as rs4441221; called by muse, mutect2
- ITGA11 | c.1296C>T p.V432= | Silent (SNP) | VAF 50/384 reads (13%) | catalogued as rs1384964854, COSV59877159; called by muse, mutect2
- ITPR1 | c.8160G>A p.K2720= (on ENST00000354582; = p.K2665= on NM_002222.7) | Silent (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2, varscan2
- KATNBL1 | c.405C>T p.S135= | Silent (SNP) | VAF 63/276 reads (23%) | called by muse, mutect2, varscan2
- KCNH6 | c.369C>T p.I123= | Silent (SNP) | VAF 75/406 reads (18%) | called by muse, mutect2, varscan2
- KCTD14 | c.75G>A p.R25= | Silent (SNP) | VAF 48/327 reads (15%) | called by muse, mutect2, varscan2
- KDM6B | c.2769C>T p.T923= | Silent (SNP) | VAF 42/338 reads (12%) | catalogued as COSV54679757; called by muse, mutect2, varscan2
- KEL | c.2145C>T p.F715= | Silent (SNP) | VAF 63/591 reads (11%) | catalogued as COSV62336390; called by muse, mutect2, varscan2
- KLHDC3 | c.591C>T p.G197= | Silent (SNP) | VAF 100/360 reads (28%) | catalogued as rs751266474; called by muse, mutect2, varscan2
- KRTAP10-2 | c.30C>T p.S10= | Silent (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- KSR2 | c.2625G>A p.K875= | Silent (SNP) | VAF 76/340 reads (22%) | called by muse, mutect2, varscan2
- LAMB2 | c.4998C>T p.L1666= | Silent (SNP) | VAF 60/354 reads (17%) | catalogued as rs143723352; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAT2 | c.663G>C p.V221= | Silent (SNP) | VAF 79/294 reads (27%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3102C>T p.P1034= | Silent (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- MAMSTR | c.324G>A p.P108= (on ENST00000318083 / NM_001130915.2; = p.P5= on NM_182574.2) | Silent (SNP) | VAF 41/312 reads (13%) | catalogued as rs370423223; called by muse, mutect2, varscan2
- MAP3K15 | c.684C>T p.F228= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as COSV58835394; called by muse, mutect2, varscan2
- MC3R | c.522C>T p.V174= | Silent (SNP) | VAF 118/462 reads (26%) | called by muse, mutect2, varscan2
- MCTP2 | c.2265G>A p.K755= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- MFSD10 | c.354G>A p.P118= | Silent (SNP) | VAF 54/245 reads (22%) | catalogued as rs1418309550, COSV53271603; called by muse, mutect2, varscan2
- MGAM2 | c.4959C>T p.I1653= | Silent (SNP) | VAF 115/336 reads (34%) | called by muse, mutect2, varscan2
- MIPOL1 | c.1236C>T p.S412= | Silent (SNP) | VAF 86/347 reads (25%) | called by muse, mutect2, varscan2
- MORC2 | c.2517C>T p.D839= (on ENST00000397641 / NM_001303256.3; = p.D777= on NM_014941.3) | Silent (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- MPP6 | c.72C>T p.F24= | Silent (SNP) | VAF 66/267 reads (25%) | catalogued as COSV56038507; called by muse, mutect2, varscan2
- MRGPRX3 | c.777C>T p.F259= | Silent (SNP) | VAF 66/401 reads (16%) | catalogued as COSV66933493; called by muse, mutect2, varscan2
- MTR | c.1344C>T p.I448= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as rs762315338, COSV100855585; called by muse, mutect2, varscan2
- MUC19 | c.6C>T p.T2= | Silent (SNP) | VAF 54/308 reads (18%) | called by muse, mutect2, varscan2
- MUC2 | c.972C>T p.H324= | Silent (SNP) | VAF 115/307 reads (37%) | called by muse, mutect2, varscan2
- MUC3A | c.105C>A p.P35= | Silent (SNP) | VAF 45/333 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.11820C>G p.T3940= | Silent (SNP) | VAF 38/634 reads (6%) | called by muse, mutect2
- MXRA5 | c.8295C>T p.I2765= | Silent (SNP) | VAF 93/305 reads (30%) | called by muse, mutect2, varscan2
- MYH3 | c.2433C>T p.S811= | Silent (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- MYO18B | c.5943C>T p.F1981= | Silent (SNP) | VAF 34/247 reads (14%) | catalogued as COSV100122777, COSV59150948; called by muse, mutect2, varscan2
- MYO1D | c.2241C>T p.F747= | Silent (SNP) | VAF 52/408 reads (13%) | catalogued as COSV59020423; called by muse, mutect2, varscan2
- NCOA7 | c.1710C>T p.P570= | Silent (SNP) | VAF 58/336 reads (17%) | catalogued as rs1421251334, COSV99997500; called by muse, mutect2, varscan2
- NEFH | c.2793G>A p.K931= | Silent (SNP) | VAF 54/369 reads (15%) | called by muse, mutect2, varscan2
- NEK10 | c.1707G>A p.R569= | Silent (SNP) | VAF 32/220 reads (15%) | called by muse, mutect2, varscan2
- NHSL1 | c.2274C>T p.P758= | Silent (SNP) | VAF 63/408 reads (15%) | called by muse, mutect2, varscan2
- NIPSNAP1 | c.813G>A p.E271= | Silent (SNP) | VAF 35/274 reads (13%) | called by muse, mutect2, varscan2
- NOBOX | c.1402C>T p.L468= | Silent (SNP) | VAF 35/276 reads (13%) | called by muse, mutect2
- NPY1R | c.42C>T p.V14= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- NTN1 | c.1008C>T p.N336= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- OAS2 | c.1620G>A p.K540= | Silent (SNP) | VAF 63/243 reads (26%) | catalogued as rs567337998, COSV100660376, COSV60801900; called by muse, mutect2, varscan2
- OR10AC1 | c.138C>T p.I46= | Silent (SNP) | VAF 182/474 reads (38%) | catalogued as rs1459719252; called by muse, mutect2, varscan2
- OR11L1 | c.651C>T p.P217= | Silent (SNP) | VAF 51/272 reads (19%) | catalogued as COSV100869484; called by muse, mutect2, varscan2
- OR13C3 | c.669C>T p.S223= | Silent (SNP) | VAF 50/341 reads (15%) | catalogued as rs759229979; called by muse, mutect2, varscan2
- OR1A1 | c.426C>T p.I142= | Silent (SNP) | VAF 68/345 reads (20%) | catalogued as COSV58404821; called by muse, mutect2, varscan2
- OR1L6 | c.528G>A p.R176= (on ENST00000373684; = p.R140= on NM_001004453.2) | Silent (SNP) | VAF 51/367 reads (14%) | called by muse, mutect2, varscan2
- OR2T34 | c.582C>T p.C194= | Silent (SNP) | VAF 47/361 reads (13%) | called by muse, mutect2, varscan2
- OR4C46 | c.891G>A p.R297= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV60218799; called by muse, mutect2, varscan2
- OR5B21 | c.882G>A p.V294= | Silent (SNP) | VAF 29/228 reads (13%) | catalogued as rs779998026, COSV64482068; called by muse, mutect2, varscan2
- OR6T1 | c.966G>A p.R322= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs866729485, COSV58309565; called by muse, mutect2, varscan2
- P2RX1 | c.501G>A p.V167= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as rs1567652529; called by muse, mutect2, varscan2
- P3H3 | c.1239C>T p.I413= | Silent (SNP) | VAF 92/319 reads (29%) | catalogued as rs781795194; called by muse, mutect2, varscan2
- PAPPA | c.2346C>T p.Y782= | Silent (SNP) | VAF 64/371 reads (17%) | called by muse, mutect2, varscan2
- PCSK5 | c.3630C>T p.A1210= | Silent (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- PKD1L1 | c.7497G>A p.G2499= | Silent (SNP) | VAF 53/436 reads (12%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6768C>T p.F2256= | Silent (SNP) | VAF 31/314 reads (10%) | catalogued as rs757030342, COSV65744484; called by muse, mutect2
- PLCH1 | c.3813G>A p.T1271= (on ENST00000340059 / NM_001130960.2; = p.T1263= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/343 reads (15%) | catalogued as rs766465810, COSV58190024; called by muse, mutect2, varscan2
- PLCH2 | c.3537C>T p.R1179= | Silent (SNP) | VAF 80/494 reads (16%) | called by muse, mutect2, varscan2
- PLD1 | c.1881C>T p.I627= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.558G>A p.V186= | Silent (SNP) | VAF 38/331 reads (11%) | called by muse, mutect2, varscan2
- PNMA5 | c.936A>G p.R312= | Silent (SNP) | VAF 148/263 reads (56%) | called by muse, mutect2, varscan2
- PROM2 | c.42G>A p.L14= | Silent (SNP) | VAF 128/518 reads (25%) | called by muse, mutect2, varscan2
- PRRC2B | c.5385C>T p.F1795= | Silent (SNP) | VAF 95/288 reads (33%) | catalogued as rs376070009; called by muse, mutect2, varscan2
- PTOV1 | c.297C>T p.L99= | Silent (SNP) | VAF 102/317 reads (32%) | catalogued as rs766648202, COSV99681542; called by muse, mutect2, varscan2
- PTPRN2 | c.1608C>T p.L536= | Silent (SNP) | VAF 67/562 reads (12%) | catalogued as rs761416498, COSV67021148; called by muse, mutect2
- RALYL | c.867G>A p.Q289= | Silent (SNP) | VAF 54/224 reads (24%) | called by muse, mutect2, varscan2
- RBM33 | c.2043C>T p.L681= | Silent (SNP) | VAF 147/392 reads (38%) | called by muse, mutect2, varscan2
- RBMXL2 | c.747G>A p.R249= | Silent (SNP) | VAF 45/322 reads (14%) | catalogued as COSV60980167; called by muse, mutect2, varscan2
- RFTN1 | c.243C>T p.A81= | Silent (SNP) | VAF 176/520 reads (34%) | called by muse, mutect2, varscan2
- RGSL1 | c.1398C>A p.P466= | Silent (SNP) | VAF 38/522 reads (7%) | called by muse, mutect2
- SCARA3 | c.1815C>T p.F605= | Silent (SNP) | VAF 34/262 reads (13%) | catalogued as COSV100107102; called by muse, mutect2, varscan2
- SECISBP2 | c.171A>G p.P57= | Silent (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- SERPINA10 | c.171G>A p.E57= | Silent (SNP) | VAF 76/580 reads (13%) | called by muse, mutect2, varscan2
- SERPING1 | c.1146C>T p.I382= | Silent (SNP) | VAF 41/358 reads (11%) | catalogued as COSV53542508; called by muse, mutect2, varscan2
- SLC22A25 | c.687C>T p.F229= | Silent (SNP) | VAF 70/235 reads (30%) | catalogued as COSV60596764, COSV60598455; called by muse, mutect2, varscan2
- SLC36A3 | c.1248C>T p.I416= | Silent (SNP) | VAF 55/311 reads (18%) | catalogued as rs752756808, COSV58855474; called by muse, mutect2, varscan2
- SLCO1B1 | c.678G>T p.L226= | Silent (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- SOX17 | c.453G>A p.V151= | Silent (SNP) | VAF 70/532 reads (13%) | catalogued as rs1308854402; called by muse, mutect2, varscan2
- SPTA1 | c.6966C>T p.F2322= | Silent (SNP) | VAF 35/346 reads (10%) | called by muse, mutect2
- SRPX2 | c.1281C>T p.D427= | Silent (SNP) | VAF 118/211 reads (56%) | called by muse, varscan2
- SYNE2 | c.17973G>A p.E5991= | Silent (SNP) | VAF 46/420 reads (11%) | catalogued as rs146253751; called by muse, mutect2, varscan2
- TBX5 | c.1143C>A p.A381= | Silent (SNP) | VAF 111/411 reads (27%) | catalogued as rs773582799; called by muse, mutect2, varscan2
- TCTA | c.48G>A p.T16= | Silent (SNP) | VAF 65/448 reads (15%) | called by muse, mutect2, varscan2
- TEKT1 | c.1200G>A p.R400= | Silent (SNP) | VAF 74/257 reads (29%) | called by muse, mutect2, varscan2
- TLK1 | c.2091C>T p.F697= | Silent (SNP) | VAF 125/276 reads (45%) | catalogued as rs757727208; called by muse, mutect2, varscan2
- TMEM115 | c.558C>G p.L186= | Silent (SNP) | VAF 58/408 reads (14%) | called by muse, mutect2, varscan2
- TMEM132D | c.639G>A p.R213= | Silent (SNP) | VAF 80/574 reads (14%) | catalogued as rs1174914505, COSV70604060; called by muse, mutect2, varscan2
- TMEM63B | c.168G>T p.L56= | Silent (SNP) | VAF 110/350 reads (31%) | called by muse, mutect2, varscan2
- TRIM29 | c.936G>A p.Q312= | Silent (SNP) | VAF 43/267 reads (16%) | called by muse, mutect2, varscan2
- TRPM1 | c.2256C>T p.I752= | Silent (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2
- UPP2 | c.549C>T p.T183= | Silent (SNP) | VAF 65/296 reads (22%) | called by muse, mutect2, varscan2
- UXS1 | c.453C>T p.I151= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as rs751183075; called by muse, mutect2, varscan2
- XKR7 | c.1503C>T p.F501= | Silent (SNP) | VAF 144/468 reads (31%) | catalogued as COSV73813086; called by muse, mutect2, varscan2
- ZC3H7B | c.1614C>T p.T538= | Silent (SNP) | VAF 36/290 reads (12%) | catalogued as rs1222138301, COSV100687463; called by muse, mutect2, varscan2
- ZDHHC22 | c.378C>T p.F126= | Silent (SNP) | VAF 66/474 reads (14%) | catalogued as rs925193854; called by muse, mutect2, varscan2
- ZHX2 | c.189G>A p.V63= | Silent (SNP) | VAF 58/402 reads (14%) | catalogued as rs867051972; called by muse, mutect2, varscan2
- ZNF208 | c.3207C>T p.P1069= | Silent (SNP) | VAF 67/382 reads (18%) | called by muse, mutect2, varscan2
- ZNF420 | c.1314G>A p.Q438= | Silent (SNP) | VAF 59/397 reads (15%) | catalogued as COSV58495617; called by muse, mutect2, varscan2
- ZNF444 | c.360C>T p.G120= | Silent (SNP) | VAF 92/349 reads (26%) | called by muse, mutect2, varscan2
- ZNF699 | c.714C>T p.F238= | Silent (SNP) | VAF 41/276 reads (15%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824182 C>T | 5'Flank (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846096 G>A | 5'Flank (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- ARRB2 | c.*39G>A | 3'UTR (SNP) | VAF 39/335 reads (12%) | catalogued as rs767220676; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990580 C>T | 5'Flank (SNP) | VAF 31/270 reads (11%) | called by muse, mutect2, varscan2
- C8orf34 | c.1106-14790G>T | Intron (SNP) | VAF 39/366 reads (11%) | called by muse, mutect2
- CFAP97 | c.1320+5451C>T | Intron (SNP) | VAF 30/186 reads (16%) | catalogued as rs755508166; called by muse, mutect2
- COL6A5 | c.*323C>A | 3'UTR (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- KCNK16 | c.802+20G>A | Intron (SNP) | VAF 43/444 reads (10%) | called by muse, mutect2
- KCNQ1 | c.1514+36543C>T | Intron (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8746G>A | Intron (SNP) | VAF 53/645 reads (8%) | called by muse, mutect2
- NBPF25P | n.1152A>T | RNA (SNP) | VAF 58/702 reads (8%) | called by muse, mutect2
- NPAP1L | n.842C>T | RNA (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2007G>A | Intron (SNP) | VAF 107/423 reads (25%) | catalogued as rs778169775; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44410C>T | Intron (SNP) | VAF 113/435 reads (26%) | catalogued as rs773510134, COSV101045020, COSV67442084; called by muse, mutect2, varscan2
- SORBS2 | c.-46+1113C>T | Intron (SNP) | VAF 69/269 reads (26%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532732 G>A | 5'Flank (SNP) | VAF 93/323 reads (29%) | catalogued as COSV55262452, COSV99742333; called by muse, mutect2, varscan2
- SUGP2 | c.-88C>T | 5'UTR (SNP) | VAF 48/316 reads (15%) | catalogued as rs1236427509; called by muse, varscan2
- TNFRSF18 | c.*48G>A | 3'UTR (SNP) | VAF 152/487 reads (31%) | catalogued as rs60038203; called by muse, mutect2, varscan2
